Somatic mutation profile of tumor specimen MMRF_1045_1_BM_CD138pos (aliquot MMRF_1045_1_BM_CD138pos_T1_KBS5U_L02849) from MMRF case MMRF_1045, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 81.3 years (29,713 days).
Specimen MMRF_1045_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c8068a10-e24c-4fea-a0e9-c0339fefc73c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1045_1_PB_WBC (Blood Derived Normal), aliquot MMRF_1045_1_PB_WBC_C3_KBS5U_L02861; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d80ff70f-8827-4b26-9a46-4bbc4828a741

The open-access MAF lists 86 somatic variants for this specimen: 29 protein-altering or splice-affecting, 14 silent, 43 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 23, Missense Mutation 23, Silent 14, Intron 11, 5'UTR 6, Splice Site 3, Nonsense Mutation 2, RNA 2, Frame Shift Del 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADGRA3 | c.2983C>T p.Q995* | Nonsense Mutation (SNP) | VAF 111/368 reads (30%) | catalogued as COSV51563654; called by muse, mutect2, varscan2
- BCL7A | c.92+2T>G p.X31_splice | Splice Site (SNP) | VAF 22/51 reads (43%) | catalogued as rs200458522; called by muse, mutect2, varscan2
- BTBD1 | c.671T>C p.L224P | Missense Mutation (SNP) | VAF 75/168 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99915164; called by muse, mutect2, varscan2
- CTTNBP2 | c.3556C>T p.Q1186* | Nonsense Mutation (SNP) | VAF 14/40 reads (35%) | catalogued as COSV50445579; called by muse, mutect2, varscan2
- CUBN | c.58G>A p.E20K | Missense Mutation (SNP) | VAF 10/281 reads (4%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as rs1334864829; called by muse, mutect2
- DIXDC1 | c.1570C>T p.R524C (on ENST00000440460 / NM_001037954.4; = p.R313C on NM_033425.4) | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs782497515; called by muse, mutect2
- GLI3 | c.4106del p.G1369Afs*50 | Frame Shift Del (DEL) | VAF 46/115 reads (40%) | catalogued as COSV67889561; called by mutect2, pindel, varscan2
- IGHV2-70 | c.113C>G p.T38R | Missense Mutation (SNP) | VAF 56/74 reads (76%) | SIFT tolerated (0.12); PolyPhen benign (0.048); catalogued as rs377422798; called by muse, varscan2
- LRIT1 | c.1290G>T p.M430I | Missense Mutation (SNP) | VAF 105/241 reads (44%) | SIFT tolerated (0.44); PolyPhen benign (0.006); catalogued as rs199510358; called by muse, mutect2, varscan2
- MRPS18B | c.703A>G p.M235V | Missense Mutation (SNP) | VAF 58/141 reads (41%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.878); catalogued as rs749787959; called by muse, mutect2, varscan2
- RNF130 | c.575G>A p.R192H | Missense Mutation (SNP) | VAF 118/241 reads (49%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.475); catalogued as rs774641021, COSV56148368; called by muse, mutect2, varscan2
- SUPT20H | c.1329T>A p.D443E (on ENST00000350612 / NM_001014286.3; = p.D444E on NM_017569.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 77/133 reads (58%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV62249293; called by muse, mutect2, varscan2
- TENM2 | c.824T>A p.L275Q (on ENST00000518659 / NM_001122679.2; = p.L84Q on NM_001080428.3) | Missense Mutation (SNP) | VAF 76/187 reads (41%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.995); catalogued as rs563352380; called by muse, mutect2, varscan2
- TENM2 | c.6112G>A p.V2038I (on ENST00000518659 / NM_001122679.2; = p.V1799I on NM_001080428.3) | Missense Mutation (SNP) | VAF 62/144 reads (43%) | SIFT tolerated (0.23); PolyPhen benign (0.172); catalogued as rs374139941; called by muse, mutect2, varscan2
- ARHGAP10 | c.1293T>G p.S431R | Missense Mutation (SNP) | VAF 57/215 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.212); called by muse, mutect2, varscan2
- CLK1 | c.524T>G p.V175G | Missense Mutation (SNP) | VAF 31/81 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ERICH6B | c.109G>A p.E37K | Missense Mutation (SNP) | VAF 78/176 reads (44%) | SIFT tolerated (0.45); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- ETV1 | c.499G>T p.A167S | Missense Mutation (SNP) | VAF 72/153 reads (47%) | SIFT tolerated (0.81); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- IGHV2-70D | c.173T>G p.I58S | Missense Mutation (SNP) | VAF 42/95 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.101); called by muse, varscan2
- IGHV3-72 | c.134G>A p.G45E | Missense Mutation (SNP) | VAF 90/199 reads (45%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.967); called by muse, varscan2
- MYCBP2 | c.6239T>C p.L2080P (on ENST00000357337; = p.L2118P on NM_015057.5) | Missense Mutation (SNP) | VAF 3/49 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.502); called by muse, mutect2
- PRKN | c.1142T>G p.F381C | Missense Mutation (SNP) | VAF 95/187 reads (51%) | SIFT tolerated (0.18); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TMEM63B | c.240-1G>A p.X80_splice | Splice Site (SNP) | VAF 33/75 reads (44%) | called by muse, mutect2, varscan2
- TRIM49C | c.1036C>T p.H346Y | Missense Mutation (SNP) | VAF 173/277 reads (62%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- TTN | c.51226A>C p.T17076P (on ENST00000591111; = p.T9652P on NM_003319.4) | Missense Mutation (SNP) | VAF 34/222 reads (15%) | PolyPhen possibly damaging (0.836); called by muse, mutect2, varscan2
- ZC3H4 | c.3638A>G p.D1213G | Missense Mutation (SNP) | VAF 27/61 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ZNF280C | c.1527+1G>A p.X509_splice | Splice Site (SNP) | VAF 79/84 reads (94%) | called by muse, mutect2, varscan2
- ZNF423 | c.2978T>C p.L993P (on ENST00000563137 / NM_001379286.1; = p.L985P on NM_015069.4) | Missense Mutation (SNP) | VAF 60/149 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.449); called by muse, mutect2, varscan2
- ZNF462 | c.5015G>A p.R1672K | Missense Mutation (SNP) | VAF 130/272 reads (48%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- ASTN1 | c.2610C>A p.I870= | Silent (SNP) | VAF 91/147 reads (62%) | called by muse, mutect2, varscan2
- ATP2B2 | c.1248G>A p.P416= (on ENST00000352432; = p.P382= on NM_001683.5) | Silent (SNP) | VAF 57/202 reads (28%) | catalogued as rs113465029, COSV59489108; called by muse, mutect2, varscan2
- CSMD1 | c.9303G>A p.P3101= (on ENST00000520002; = p.P3100= on NM_033225.6) | Silent (SNP) | VAF 42/105 reads (40%) | catalogued as rs761115346, COSV59281702, COSV59317968; called by muse, mutect2, varscan2
- EMCN | c.618A>G p.V206= | Silent (SNP) | VAF 134/497 reads (27%) | catalogued as rs1325619508; called by muse, mutect2, varscan2
- FREM1 | c.5832C>T p.D1944= | Silent (SNP) | VAF 23/46 reads (50%) | catalogued as COSV66525833; called by muse, mutect2, varscan2
- IGHV2-70D | c.60G>A p.Q20= | Silent (SNP) | VAF 64/75 reads (85%) | called by muse, varscan2
- MMRN2 | c.1152C>T p.H384= | Silent (SNP) | VAF 70/148 reads (47%) | called by muse, mutect2, varscan2
- NAV3 | c.5343G>A p.V1781= | Silent (SNP) | VAF 54/119 reads (45%) | called by muse, mutect2, varscan2
- OTOGL | c.1038T>C p.V346= (on ENST00000547103; = p.V337= on NM_173591.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 28/73 reads (38%) | called by mutect2, varscan2
- PSD | c.2067C>T p.G689= | Silent (SNP) | VAF 20/39 reads (51%) | called by muse, mutect2, varscan2
- SAE1 | c.24C>T p.G8= | Silent (SNP) | VAF 17/40 reads (43%) | catalogued as rs370745297; called by muse, mutect2, varscan2
- SCN7A | c.3420A>G p.T1140= | Silent (SNP) | VAF 34/56 reads (61%) | catalogued as rs1359309553; called by muse, mutect2, varscan2
- UTP25 | c.1353C>G p.S451= | Silent (SNP) | VAF 9/38 reads (24%) | called by muse, mutect2, varscan2
- ZMYM4 | c.213T>C p.D71= | Silent (SNP) | VAF 199/411 reads (48%) | called by muse, mutect2, varscan2
- ABCB9 | c.*193T>A | 3'UTR (SNP) | VAF 39/95 reads (41%) | called by muse, mutect2, varscan2
- AC008080.1 | n.292G>A | RNA (SNP) | VAF 16/81 reads (20%) | catalogued as rs900569529; called by muse, mutect2, varscan2
- ADAMTS3 | c.*10C>A | 3'UTR (SNP) | VAF 152/478 reads (32%) | catalogued as rs201954148; called by muse, mutect2, varscan2
- ATP8A2 | c.3184-34369C>T | Intron (SNP) | VAF 20/64 reads (31%) | called by muse, mutect2, varscan2
- ATP8B1 | c.181+1372C>T | Intron (SNP) | VAF 11/26 reads (42%) | catalogued as rs912760036; called by muse, mutect2, varscan2
- ATXN2 | c.3745-947_3745-946del | Intron (DEL) | VAF 35/110 reads (32%) | called by pindel, varscan2
- BAG4 | c.*815T>G | 3'UTR (SNP) | VAF 50/112 reads (45%) | called by muse, mutect2, varscan2
- CALD1 | c.*2129C>A | 3'UTR (SNP) | VAF 62/143 reads (43%) | catalogued as rs1424309009; called by muse, mutect2, varscan2
- CASK | chrX:41515347 A>G | 3'Flank (SNP) | VAF 29/31 reads (94%) | called by muse, mutect2, varscan2
- CCDC8 | c.-71C>T | 5'UTR (SNP) | VAF 97/198 reads (49%) | called by muse, mutect2, varscan2
- CCNT1 | c.*269C>G | 3'UTR (SNP) | VAF 46/111 reads (41%) | called by muse, mutect2, varscan2
- CFAP44 | c.5373+691C>T | Intron (SNP) | VAF 15/53 reads (28%) | catalogued as rs745467952; called by muse, mutect2, varscan2
- CHST11 | c.*3003dup | 3'UTR (INS) | VAF 40/95 reads (42%) | catalogued as rs376255851; called by mutect2, varscan2
- CLEC16A | c.1815+44T>C | Intron (SNP) | VAF 76/171 reads (44%) | called by muse, mutect2
- CST9LP1 | n.307G>C | RNA (SNP) | VAF 34/80 reads (43%) | called by muse, mutect2, varscan2
- DIO2 | c.*4317G>A | 3'UTR (SNP) | VAF 37/67 reads (55%) | called by muse, mutect2, varscan2
- DOCK1 | c.*103G>A | 3'UTR (SNP) | VAF 161/389 reads (41%) | called by muse, mutect2, varscan2
- DTX3 | c.1+104C>A | Intron (SNP) | VAF 252/548 reads (46%) | called by muse, mutect2, varscan2
- EBF2 | c.*792T>C | 3'UTR (SNP) | VAF 44/90 reads (49%) | called by muse, mutect2, varscan2
- ELOVL2 | c.*2584_*2586del | 3'UTR (DEL) | VAF 54/136 reads (40%) | called by pindel, varscan2
- FES | c.669-22G>T | Intron (SNP) | VAF 11/35 reads (31%) | called by muse, mutect2, varscan2
- FOXL2 | c.*767T>A | 3'UTR (SNP) | VAF 5/81 reads (6%) | catalogued as rs1162459052; called by muse, mutect2
- GUCY2C | c.-75T>C | 5'UTR (SNP) | VAF 45/88 reads (51%) | called by muse, mutect2, varscan2
- KCNC2 | c.*1075A>G | 3'UTR (SNP) | VAF 39/68 reads (57%) | called by muse, mutect2, varscan2
- MAP9 | c.*2932C>G | 3'UTR (SNP) | VAF 23/89 reads (26%) | called by muse, mutect2, varscan2
- NBEAL2 | c.6199-16C>T | Intron (SNP) | VAF 62/156 reads (40%) | called by muse, mutect2, varscan2
- NEBL | c.*5713T>C | 3'UTR (SNP) | VAF 43/88 reads (49%) | called by muse, mutect2, varscan2
- NGFR | c.*94dup | 3'UTR (INS) | VAF 40/91 reads (44%) | catalogued as rs879366470; called by mutect2, varscan2
- NR4A2 | c.*661A>C | 3'UTR (SNP) | VAF 82/179 reads (46%) | called by muse, mutect2, varscan2
- PLSCR5 | c.-390G>A | 5'UTR (SNP) | VAF 67/105 reads (64%) | called by muse, mutect2, varscan2
- PTP4A3 | c.-442G>A | 5'UTR (SNP) | VAF 40/74 reads (54%) | catalogued as rs939821299; called by muse, mutect2, varscan2
- RANGAP1 | c.*894C>T | 3'UTR (SNP) | VAF 73/141 reads (52%) | called by muse, mutect2, varscan2
- RPS15A | c.300-106A>C | Intron (SNP) | VAF 62/132 reads (47%) | called by muse, mutect2, varscan2
- SAMD8 | c.*410A>G | 3'UTR (SNP) | VAF 60/130 reads (46%) | called by muse, mutect2, varscan2
- SCIMP | c.22-27T>G | Intron (SNP) | VAF 55/108 reads (51%) | catalogued as COSV68310726; called by muse, mutect2, varscan2
- SMAD9 | c.*2498T>C | 3'UTR (SNP) | VAF 42/98 reads (43%) | called by muse, mutect2, varscan2
- TPD52 | c.-181G>C | 5'UTR (SNP) | VAF 31/70 reads (44%) | called by muse, mutect2, varscan2
- TRAM1L1 | c.*420A>C | 3'UTR (SNP) | VAF 78/129 reads (60%) | called by muse, mutect2, varscan2
- UNC5D | c.*4238T>C | 3'UTR (SNP) | VAF 31/69 reads (45%) | called by muse, mutect2, varscan2
- USP3 | c.*245T>C | 3'UTR (SNP) | VAF 28/64 reads (44%) | called by muse, mutect2, varscan2
- ZNF280D | c.2260-23_2260-19del | Intron (DEL) | VAF 14/42 reads (33%) | called by pindel, varscan2
- ZNF584 | c.-79C>G | 5'UTR (SNP) | VAF 45/111 reads (41%) | called by muse, mutect2, varscan2
- ZNF844 | c.*3662T>A | 3'UTR (SNP) | VAF 4/77 reads (5%) | called by muse, mutect2
